Somatic mutation profile of tumor specimen 6968a80f-fd06-4669-b4bd-9a5cb5 (aliquot 6968a80f-fd06-4669-b4bd-9a5cb5_D6) from CPTAC case 05CO014, project CPTAC-2 (Rectum — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 6968a80f-fd06-4669-b4bd-9a5cb5: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5452c5-1846-4f38-acf0-29dceb281848.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen acf5eda7-4858-4a52-8ebd-54326f (Blood Derived Normal), aliquot acf5eda7-4858-4a52-8ebd-54326f_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59fcea0c-5150-4c08-aa00-90893acc996a

The open-access MAF lists 118 somatic variants for this specimen: 78 protein-altering or splice-affecting, 30 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 30, Nonsense Mutation 7, Intron 5, Frame Shift Del 5, Splice Region 2, Splice Site 2, RNA 2, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 63/271 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | hotspot (GDC flag); catalogued as rs1164096095, COSV62258353; called by muse, mutect2, varscan2
- ADAMTS2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 173/522 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371384169; called by muse, mutect2, varscan2
- AFAP1L1 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs755708543; called by muse, mutect2, varscan2
- ANTKMT | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1409427063; called by muse, mutect2, varscan2
- APC | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 136/410 reads (33%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by muse, mutect2, varscan2
- ARMH1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as rs1444023945; called by muse, mutect2, varscan2
- BEX4 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs1210792274, COSV101015316; called by muse, mutect2
- C1S | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs781863865, COSV61072455; called by muse, varscan2
- C2CD2L | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs774952377, COSV60883922; called by mutect2, varscan2
- CCDC110 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as rs1176222863, COSV56870390; called by muse, mutect2, varscan2
- CDC14A | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 34/334 reads (10%) | catalogued as rs770995792; called by muse, mutect2
- DISP3 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 69/192 reads (36%) | catalogued as COSV53820486; called by muse, mutect2, varscan2
- EPB41L3 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV59464378; called by mutect2, varscan2
- ESCO2 | c.1353+1G>T p.X451_splice | Splice Site (SNP) | VAF 17/117 reads (15%) | catalogued as rs959080745; called by muse, mutect2, varscan2
- FAT4 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as COSV101272912; called by muse, mutect2, varscan2
- FAT4 | c.11449G>T p.G3817W | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627355, COSV100630540; called by muse, mutect2, varscan2
- FBXW7 | c.1787C>T p.S596F (on ENST00000281708 / NM_001349798.2; = p.S516F on NM_018315.5) | Missense Mutation (SNP) | VAF 196/329 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55905007, COSV55968840, COSV55969630; called by muse, mutect2, varscan2
- GLE1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1290402597, COSV104401604; called by muse, mutect2, varscan2
- H3C6 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as rs911990384, COSV100839038; called by muse, mutect2, varscan2
- HBM | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 70/716 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs747177626; called by muse, mutect2
- HK3 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 162/525 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs776797141, COSV52842032; called by muse, varscan2
- KCNH7 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs374095828, COSV59795271; called by muse, mutect2, varscan2
- MCM3AP | c.4999G>A p.G1667R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs777598152, COSV52437920, COSV99387306; called by muse, mutect2, varscan2
- MKRN3 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs772391409, COSV100090824, COSV58812095; called by muse, mutect2, varscan2
- NOS3 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs758240936, COSV99871693; called by muse, mutect2, varscan2
- NRG2 | c.990C>T p.S330= | Splice Region (SNP) | VAF 38/124 reads (31%) | catalogued as rs765915567, COSV56834910, COSV56839255; called by muse, mutect2, varscan2
- PAGE1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as rs781908016, COSV65998716; called by muse, mutect2, varscan2
- SACS | c.5630G>A p.R1877Q | Missense Mutation (SNP) | VAF 154/494 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as rs772866081, COSV66534922; called by mutect2, varscan2
- SDC4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as rs202142981; called by muse, mutect2, varscan2
- SLC10A6 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148050314; called by muse, mutect2, varscan2
- SPEM2 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs117934604; called by muse, mutect2, varscan2
- SYT1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1193400094, COSV54070574; called by muse, mutect2, varscan2
- TMEM47 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1488670302, COSV99327901; called by muse, mutect2, varscan2
- TNNT1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759548188, COSV52571164; called by muse, mutect2, varscan2
- TRAPPC4 | c.460_461del p.K154Vfs*8 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs1161494286; called by mutect2, pindel, varscan2
- TSSC4 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs766231949, COSV50215864; called by muse, mutect2, varscan2
- TTC21A | c.1793T>C p.V598A | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as rs1410087097; called by muse, mutect2, varscan2
- ZXDB | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs776323254; called by muse, mutect2
- ABCB11 | c.2967G>C p.Q989H | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ANKRD17 | c.4123G>T p.A1375S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2
- APC | c.3778_3785del p.Q1260Lfs*13 | Frame Shift Del (DEL) | VAF 62/209 reads (30%) | called by mutect2, pindel, varscan2
- ARID4A | c.893_896del p.T298Kfs*79 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- CDCA7L | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD9 | c.6328G>A p.E2110K | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- COL6A5 | c.2704G>T p.A902S | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CPA5 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- DPF2 | c.976_978dup p.E326dup | In Frame Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- ENC1 | c.1394dup p.Y465* | Nonsense Mutation (INS) | VAF 127/417 reads (30%) | called by mutect2, pindel, varscan2
- EVC2 | c.3563A>G p.H1188R | Missense Mutation (SNP) | VAF 152/480 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FAM189B | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HSD3B2 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 198/670 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- HSPG2 | c.2771G>A p.C924Y | Missense Mutation (SNP) | VAF 271/729 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KAT6A | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KIF26A | c.3758A>G p.Q1253R | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KLHL32 | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 100/466 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- MTA2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 101/359 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MUC19 | c.704C>A p.T235N | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ODAM | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PDCL | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKD1 | c.12322T>A p.W4108R (on ENST00000262304 / NM_001009944.3; = p.W4107R on NM_000296.4) | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLK1 | c.1678del p.R560Afs*5 | Frame Shift Del (DEL) | VAF 180/545 reads (33%) | called by mutect2, pindel, varscan2
- PNISR | c.1327+1G>A p.X443_splice | Splice Site (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 63/345 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PSG5 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- RALGAPA1 | c.1587G>A p.Q529= | Splice Region (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- RIMBP3 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 60/549 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- RNASE13 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERAC1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SLC4A3 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SOX9 | c.754del p.L252* | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | called by mutect2, pindel, varscan2
- SPOCK3 | c.1251T>A p.D417E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- SYP | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 202/462 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX2 | c.2720C>T p.T907I (on ENST00000583097 / NM_001288733.2; = p.T914I on NM_018469.5) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TST | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- URB1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ZFP36L2 | c.698dup p.R234Afs*240 | Frame Shift Ins (INS) | VAF 86/152 reads (57%) | called by mutect2, pindel, varscan2
- ZNF28 | c.1187C>G p.S396* | Nonsense Mutation (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- ADAMTS20 | c.210G>A p.A70= | Silent (SNP) | VAF 135/410 reads (33%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1764C>T p.A588= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs767928378, COSV51675490; called by muse, mutect2, varscan2
- CARS1 | c.819G>A p.A273= | Silent (SNP) | VAF 92/190 reads (48%) | catalogued as rs373450907, COSV53461068; called by muse, varscan2
- CASKIN2 | c.2277C>T p.P759= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, varscan2
- CPAMD8 | c.3219G>A p.T1073= (on ENST00000651564; = p.T1026= on NM_015692.5) | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs375943617; called by muse, mutect2, varscan2
- DCAF8L1 | c.792G>A p.Q264= | Silent (SNP) | VAF 190/748 reads (25%) | called by muse, mutect2, varscan2
- EN1 | c.1065C>T p.R355= | Silent (SNP) | VAF 197/489 reads (40%) | catalogued as COSV54630332; called by muse, mutect2, varscan2
- FAT2 | c.9705G>A p.T3235= | Silent (SNP) | VAF 189/613 reads (31%) | catalogued as rs537852650; called by muse, mutect2, varscan2
- GCNT2 | c.891C>T p.D297= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs150542637; called by muse, mutect2, varscan2
- LCOR | c.2988C>T p.N996= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as rs756779031; called by muse, mutect2, varscan2
- LEFTY1 | c.975C>G p.P325= | Silent (SNP) | VAF 112/356 reads (31%) | called by muse, mutect2, varscan2
- MAP3K6 | c.720G>A p.R240= | Silent (SNP) | VAF 68/205 reads (33%) | called by muse, mutect2, varscan2
- NACC2 | c.1278C>T p.P426= | Silent (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- NPTXR | c.1041C>T p.N347= | Silent (SNP) | VAF 87/222 reads (39%) | catalogued as rs759385529; called by muse, mutect2, varscan2
- OR52L1 | c.243G>A p.L81= | Silent (SNP) | VAF 66/300 reads (22%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1923C>T p.D641= | Silent (SNP) | VAF 67/161 reads (42%) | catalogued as rs373092547; called by muse, mutect2, varscan2
- PCDH8 | c.1746C>T p.S582= | Silent (SNP) | VAF 150/282 reads (53%) | called by muse, mutect2, varscan2
- PINLYP | c.249C>T p.G83= | Silent (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- PLXNB3 | c.2001C>T p.S667= | Silent (SNP) | VAF 65/237 reads (27%) | catalogued as rs142473436, COSV62796150; called by muse, mutect2, varscan2
- PNPLA7 | c.1045C>T p.L349= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- RHCG | c.549C>T p.T183= | Silent (SNP) | VAF 90/185 reads (49%) | called by muse, mutect2, varscan2
- RP1 | c.984C>T p.D328= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs776574526, COSV55113924; ClinVar: likely benign; called by muse, mutect2, varscan2
- THSD7A | c.243G>A p.T81= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV70261995; called by muse, mutect2, varscan2
- TNP2 | c.159G>A p.P53= | Silent (SNP) | VAF 13/192 reads (7%) | catalogued as rs528680523; called by muse, mutect2
- TRPC4 | c.639C>T p.S213= | Silent (SNP) | VAF 113/364 reads (31%) | called by muse, mutect2, varscan2
- UPRT | c.289C>T p.L97= | Silent (SNP) | VAF 30/247 reads (12%) | catalogued as rs1276786565, COSV64912711; called by muse, mutect2, varscan2
- ZCCHC7 | c.429A>G p.E143= | Silent (SNP) | VAF 95/269 reads (35%) | called by muse, mutect2, varscan2
- ZIC1 | c.264C>T p.S88= | Silent (SNP) | VAF 40/266 reads (15%) | called by muse, mutect2, varscan2
- ZIC1 | c.831G>A p.P277= | Silent (SNP) | VAF 44/255 reads (17%) | catalogued as rs745710668, COSV51550396; called by muse, mutect2, varscan2
- ZNF654 | c.2469C>T p.N823= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as rs746078281, COSV58805470, COSV58806203; called by muse, mutect2, varscan2
- AC135782.1 | n.416G>A | RNA (SNP) | VAF 77/226 reads (34%) | catalogued as rs1189587145; called by muse, mutect2, varscan2
- ARHGEF4 | c.-109+139C>T | Intron (SNP) | VAF 32/166 reads (19%) | catalogued as COSV100388745; called by muse, mutect2, varscan2
- CLUHP11 | n.289T>G | RNA (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- DAZAP2 | c.-43A>G | 5'UTR (SNP) | VAF 34/87 reads (39%) | catalogued as rs376713335; called by muse, mutect2, varscan2
- GRIK5 | c.2514+1194G>T | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- GYPB | c.38-1342C>T | Intron (SNP) | VAF 59/174 reads (34%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-401C>G | Intron (SNP) | VAF 45/221 reads (20%) | catalogued as rs1275975861; called by muse, mutect2, varscan2
- PHACTR1 | c.1510-2451G>T | Intron (SNP) | VAF 69/235 reads (29%) | called by muse, mutect2, varscan2
- SCAF11 | chr12:45991975 C>G | 5'Flank (SNP) | VAF 39/128 reads (30%) | catalogued as rs939996598; called by muse, mutect2, varscan2
- TLX2 | c.*139C>T | 3'UTR (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
